Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A02R, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A02R-01A (Primary Tumor).

TCGA #:

Internal Sample ID:

Diagnosis:

The present material involves an invasive, poorly differentiated carcinoma (G 3) with penetration of all wall layers (corresponding to at least p T 3) and with lymph and blood vessel invasion (L 1, V 1), as well as free lymph nodes and free resection margins.

Provisional tumor classification:
p T at least 3, p N 0, M X, R 0.

ICD - 0 - 3

Path report - Carcinoma, NOS 8010/3

CQCF - Adenocarcinoma, NOS 8140/3

Site: Cecum (per CQCF) C18.0 lw 3/30/11

Confirmation of the epithelial nature by demonstration of what is known as total keratin.

Marked S100 protein positivity.

In addition, positive reaction for chromogranin, focally also synaptophysin.

The findings therefore point to a neuro-endocrine carcinoma in the area stated.

HPA Discrepancy		☒

Source: NCI Genomic Data Commons file 7544af64-1df8-44c3-8664-f41d5c486cde (TCGA-AA-A02R.11E660AD-07D5-4996-A054-5F55D68AB793.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).